Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2R7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2R7-01A (Primary Tumor).

[page 1 of 4]
Surgical Final Report Temporary Copy

Page 1 of 4

Case:
Collected:
Ordered by:

Patient:
ID:
Location:

MS Specimen

A) Right common iliac lymph node. B) Uterus, cervix, bilateral ovaries/fallopian tubes. C) Right pelvic lymph nodes. D) Precaval and right periaortic lymph node. E) Left pelvic lymph nodes. F) Left upper common and periaortic lymph nodes.

MS Clinical History

Cervical cancer.

1 CD-0-3
carcinoma, squamous cell, NOS 8070/3
Site: cervix, NOS C53.9
9/8/11

MS Gross Description

The specimen is received fresh in 6 containers designated with the patient's name

Part A is designated "right common iliac lymph node". The specimen consists of a 2.7 cm in greatest dimension single lymph node. The cut surface is tan to pink with a slight lobular architecture. The lymph node appears grossly positive for tumor involvement. A portion of the lymph node is taken for the protocol.

A1 Additional cross sections of the lymph node

Part B is designated "cervix, uterus, bilateral tubes and ovaries". The specimen consists of a 9.7 x 6.0 x 4.9 cm, 192 g uterus with bilateral attached ovaries and fallopian tubes. The uterine serosal surface is tan to pink and distended by underlying myometrial nodules. There are bilateral attached ovaries and fallopian tubes. The cervix is 3.2 cm in diameter. Surrounding the cervix is a vaginal cuff from 2.3 cm to 2.7 cm in width. The vaginal mucosa is tan and grossly normal. The left fallopian tube is 3.2 cm in length with a diameter of 0.6 cm and has a normal architecture. The left ovary is 2.7 cm in greatest dimension. The ovarian cut surface contains a unilocular simple cyst, 0.7 cm in greatest dimension. The right fallopian tube is 4.3 cm in length with a diameter of 0.6 cm and has a normal architecture. The right ovary contains 2 unilocular cysts, 0.4 cm and 0.7 cm in greatest dimension. The cervix contains a 2.3 x 1.4 x 0.5 cm tan lobular mass primarily involving the posterior cervix. The cut surface of the mass demonstrates a lesion extending to a depth of approximately 0.3 cm. The mass is 4 cm from the posterior vaginal surgical margin and 2.1 cm from the posterior paracervical soft tissue surgical margin, 2.7 cm from the left soft tissue surgical margin, 3.3 cm from the right soft tissue surgical margin, and 2.7 cm from the anterior soft tissue margin. The cut surface demonstrates the mass does superficially extend to involve the anterior cervix. The mass does not grossly involve the lower uterine segment.

- B1 Representative sections of the left ovary and fallopian tube
- B2 Representative sections of the right ovary and fallopian tube
- B3-B4 Full thickness section of the anterior uterus
- B5-B6 Full thickness section from the posterior uterus
- B7-B9 Representative sections of the myometrial nodules
- B10-B11 En face posterior vaginal mucosa surgical margin

[page 2 of 4]
**Surgical Final Report .
Temporary Copy**

Page 2 of 4

Case:

Collected: ,

Ordered by:

Patient:

ID:

Location:

- B12 En face anterior vaginal mucosa surgical margin
- B13-B14 Full thickness section of the posterior cervix including underlying soft tissue surgical margin
- B15 Left cervical mass
- B16 Right cervical mass
- B17-B18 Anterior cervical mass, bisected (includes the anterior soft tissue margin)
- B19 Lower uterine segment

Part C is designated "right pelvic lymph nodes". The specimen consists of a portion of fibroadipose tissue containing 11 lymph nodes up to 2.3 cm in greatest dimension.

- C1 Two lymph nodes, each bisected, one inked black
- C2 Two lymph nodes, each bisected, one inked black
- C3 Two lymph nodes, one is trisected, the remaining lymph node is inked black and left intact
- C4 One lymph node, trisected
- C5 One lymph node, bisected
- C6 One lymph node
- C7 One lymph node, bisected
- C8-C10 One lymph node

Part D is designated "precaval + right periaortic lymph nodes". The specimen consists of a portion of fibroadipose tissue containing a single lymph node up to 0.7 cm in greatest dimension.

- D1 One lymph node, bisected

Part E is designated "left pelvic lymph nodes". The specimen consists of a portion of fibroadipose tissue containing 7 lymph nodes up to 2.8 cm in greatest dimension.

- E1 One lymph node
- E2 One lymph node
- E3 One lymph node
- E4 One lymph node, bisected
- E5-E6 One lymph node, bisected
- E7 One lymph node, bisected
- E8-E12 One lymph node

Part F is designated "left upper common + periaortic lymph node". The specimen consists of a portion of fibroadipose tissue containing 2 lymph nodes, 0.7 cm and 0.9 cm in greatest dimension.

- F1 One lymph node, trisected
- F2 One lymph node, bisected

[page 3 of 4]
**Surgical Final Report |
Temporary Copy**

Page 3 of 4

Case:
Collected:
Ordered by:

Patient:
ID:
Location:

MS Microscopic Description

B13-B16: Sections of squamous cell carcinoma

B13: Representative section of tumor

A1: Metastatic lymph node

MS Diagnosis

- A: Right common iliac lymph node:
Metastatic squamous cell carcinoma (1/1, 1.2 cm, negative for extranodal extension).
- B: Uterus, cervix, bilateral tubes and ovaries, hysterectomy:
Poorly differentiated squamous cell carcinoma of cervix, pT1b1.
Benign inactive endometrium.
Leiomyomata.
Paratubal endometriosis.
Unremarkable bilateral ovaries with follicular cysts
- C: Right pelvic lymph nodes, regional dissection:
Negative for malignancy (0/11).
- D: Precaval and right periaortic lymph nodes:
Negative for malignancy (0/1).
- E: Left pelvic lymph nodes, regional dissection:
Negative for malignancy (0/7).
- F: Left upper common and periaortic lymph nodes:
Negative for malignancy (0/2).

MS Comment

B: Cervix, Microscopic

HISTOLOGIC TYPE:

Squamous cell carcinoma

HISTOLOGIC GRADE:

G3: Poorly differentiated

PRIMARY TUMOR (pT) TNM [FIGO]:

pT1b1 [IB1]: Cervical carcinoma confined to uterus, clinically visible lesion 4.0 cm or less in greatest dimension

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 22

Number involved: 1

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of tumor from closest margin: 21 mm

Specify margin, if possible: Paracervical margin, posterior.

Carcinoma in situ absent at distal margin

*VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

[page 4 of 4]
Surgical Final Report
Temporary Copy

Page 4 of 4

Case:
Collected:
Ordered by
*Present

Patient:
ID: :
Location:

MS Transcribed:

MD
(Electronic Signature)

Source: NCI Genomic Data Commons file 820724c0-3183-4b87-9ad6-938b7d5f6a98 (TCGA-EK-A2R7.5EE5A64B-9025-4C3E-8CD8-8293515BC1F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).